HCMI case HCM-BROD-0694-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f25dac3c-3ee1-4a5e-898a-8b4e6b12ebc2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1971; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 45.9 years (16,765 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IV; AJCC pathologic T: T1a; AJCC pathologic N: N3b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Dabrafenib + Trametinib; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 863 days (2.4 years); Days to treatment end: 890 days (2.4 years).
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,035 days (2.8 years); Days to treatment end: 1,035 days (2.8 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,044 days (2.9 years); Days to treatment end: 1,064 days (2.9 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Nivolumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,044 days (2.9 years); Days to treatment end: 1,064 days (2.9 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C77.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of inguinal region or leg; Classification of tumor: metastasis; Age at diagnosis: 48.2 years (17,596 days); Days to diagnosis: 831 days (2.3 years); Satellite nodule present: Absent.
   Pathology details: Breslow thickness category: <=1 mm; Lymph nodes positive: 4; Lymph nodes tested: 14; Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (2 entries)
- Days to follow up: 1,437 days (3.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 1,030.

Molecular and laboratory tests
- BRAF mutation, nos: Positive; Amino-acid change: V600E.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 58 kg; Height: 175 cm; BMI: 18.9.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0694-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0694-C43-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 35; Percent tumor nuclei: 65; Percent normal cells: 30; Percent necrosis: 35; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0694-C43-06A-01-S1-HE: Section location: Top; Percent tumor cells: 35; Percent tumor nuclei: 60; Percent normal cells: 55; Percent necrosis: 10; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0694-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0694-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
